Somatic mutation profile of tumor specimen TCGA-XF-A8HF-01A (aliquot TCGA-XF-A8HF-01A-11D-A364-08) from TCGA case TCGA-XF-A8HF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.2 years (29,288 days).
Specimen TCGA-XF-A8HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b249f33d-2257-484c-bc6b-4648bfd30bb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A8HF-10A (Blood Derived Normal), aliquot TCGA-XF-A8HF-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5534951a-92c0-479d-b354-dcfd930c44c0

The open-access MAF lists 170 somatic variants for this specimen: 130 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 35, Nonsense Mutation 7, Splice Site 4, Frame Shift Del 3, 5'UTR 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2168A>G p.Q723R | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV53965435, COSV53967772; called by muse, mutect2, varscan2
- ABCC9 | c.2167C>A p.Q723K | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.542); catalogued as rs1246152628, COSV53965456; called by muse, mutect2, varscan2
- AC093512.2 | c.*833+1G>A | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV57632269; called by muse, mutect2, varscan2
- ACY3 | c.230T>G p.F77C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as COSV54828327; called by muse, mutect2, varscan2
- ADAL | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as COSV101052576; called by muse, mutect2, varscan2
- ADGRF4 | c.1635A>C p.R545S | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51950457; called by muse, mutect2
- ADH1B | c.218T>C p.I73T | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV59295625; called by muse, mutect2, varscan2
- AFAP1 | c.526A>C p.I176L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV61794220; called by muse, mutect2, varscan2
- AHNAK2 | c.12623A>C p.K4208T | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1361901424, COSV60910707; called by muse, mutect2
- AL121899.2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV67350026; called by muse, mutect2, varscan2
- ANK3 | c.7814A>T p.E2605V | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55049145, COSV55073779; called by muse, mutect2, varscan2
- ANK3 | c.7813G>T p.E2605* | Nonsense Mutation (SNP) | VAF 57/137 reads (42%) | catalogued as COSV99782309; called by muse, mutect2, varscan2
- ARHGAP30 | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63515355; called by muse, mutect2, varscan2
- ARHGAP32 | c.1676T>A p.I559N (on ENST00000310343 / NM_001378025.1; = p.I210N on NM_014715.4) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59844712; called by muse, mutect2
- ARHGEF26 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.085); catalogued as rs1228138089, COSV62844769; called by muse, mutect2, varscan2
- ARMC3 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.376); catalogued as COSV53058586, COSV53069373; called by muse, mutect2
- B3GNT7 | c.688T>C p.C230R | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746075711, COSV55006020; called by muse, mutect2, varscan2
- BAZ2A | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99467659; called by muse, mutect2, varscan2
- BDP1 | c.6577G>A p.E2193K | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV62429827; called by muse, mutect2, varscan2
- BOC | c.2842C>G p.P948A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.024); catalogued as COSV56348393; called by muse, mutect2
- C2orf16 | c.1952C>G p.P651R | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV62674401; called by muse, mutect2, varscan2
- CC2D1A | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV58781920; called by muse, mutect2, varscan2
- CCDC157 | c.2096G>T p.R699L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs745704312, COSV53175593, COSV53175696; called by muse, varscan2
- CCDC88C | c.2056C>A p.Q686K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as COSV66235669; called by muse, mutect2
- CDH10 | c.445A>C p.K149Q | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52574367; called by muse, mutect2
- CDH10 | c.443T>A p.I148N | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52574372; called by muse, mutect2
- CDH16 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs543181678, COSV55335600, COSV55336537; called by muse, mutect2, varscan2
- CFLAR | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.039); catalogued as COSV58579620; called by muse, mutect2, varscan2
- CIT | c.5301G>T p.K1767N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV55863443; called by muse, mutect2, varscan2
- COL17A1 | c.1145C>G p.S382C | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV62225783, COSV62230079; called by muse, mutect2, varscan2
- CST7 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54173021; called by muse, mutect2, varscan2
- CUZD1 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59025951; called by muse, mutect2, varscan2
- CYP26B1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779814291, COSV50011058; called by muse, varscan2
- DCC | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 75/99 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs543242235, COSV59091535; called by muse, mutect2, varscan2
- DDX11 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99300249; called by muse, mutect2, varscan2
- DIPK2A | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.27); PolyPhen benign (0.217); catalogued as rs1241525570, COSV59856713, COSV59856830; called by muse, mutect2, varscan2
- DLC1 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV52295382, COSV52300994; called by muse, mutect2, varscan2
- DNAJB2 | c.335C>G p.P112R | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60676042; called by muse, mutect2, varscan2
- DZIP1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV61264586; called by muse, mutect2, varscan2
- ELAPOR1 | c.1771T>G p.C591G | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64040138; called by muse, mutect2, varscan2
- ELF3 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100668882; called by muse, mutect2, varscan2
- ELMO2 | c.308C>A p.A103D | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV51681896; called by muse, mutect2, varscan2
- EMILIN1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66694339, COSV66694411; called by muse, mutect2, varscan2
- EMILIN2 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.175); catalogued as COSV54422042; called by muse, mutect2, varscan2
- EXPH5 | c.3996C>G p.F1332L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56200072; called by muse, mutect2, varscan2
- FARP1 | c.1693-2A>G p.X565_splice | Splice Site (SNP) | VAF 111/189 reads (59%) | catalogued as COSV60332480; called by muse, mutect2, varscan2
- FAT2 | c.5569C>A p.Q1857K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55815653; called by muse, mutect2, varscan2
- FBXL14 | c.909del p.L304Wfs*47 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as rs1379260306; called by mutect2, pindel, varscan2
- FOXD4 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV58698906; called by muse, mutect2
- GAS7 | c.1139-2A>T p.X380_splice (on ENST00000432992 / NM_201433.2; = p.X240_splice on NM_003644.3) | Splice Site (SNP) | VAF 26/68 reads (38%) | catalogued as COSV60433056; called by muse, mutect2, varscan2
- GDPD5 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as COSV61126813; called by muse, mutect2
- GLB1L2 | c.939C>A p.N313K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60277913; called by muse, mutect2
- GTSE1 | c.1722G>A p.M574I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV101483257; called by muse, mutect2
- H4C13 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 72/105 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV60693439; called by muse, mutect2, varscan2
- INTS6 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 34/212 reads (16%) | catalogued as COSV100247262; called by muse, mutect2, varscan2
- IPMK | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV64243517; called by muse, mutect2, varscan2
- ITGBL1 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV66006443; called by muse, mutect2, varscan2
- ITIH4 | c.2407G>A p.V803M | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); catalogued as COSV56572320; called by muse, mutect2, varscan2
- KCNC2 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs776508803, COSV100128253; called by muse, varscan2
- KCNQ5 | c.1254G>C p.K418N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100573057; called by muse, mutect2
- KIF13A | c.3919A>C p.I1307L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV52445729; called by muse, mutect2, varscan2
- L3MBTL1 | c.1313G>C p.G438A (on ENST00000418998 / NM_001377303.1; = p.G348A on NM_015478.7) | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100916876, COSV100916984, COSV64228097; called by muse, mutect2
- LAMC3 | c.3716T>C p.V1239A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV62653658; called by muse, mutect2, varscan2
- LDB3 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 59/65 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53937365, COSV53939198; called by muse, mutect2, varscan2
- LRRC2 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV56125376; called by muse, mutect2, varscan2
- MAGI1 | c.3120C>A p.N1040K (on ENST00000402939 / NM_001033057.2; = p.N1069K on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV58318713; called by muse, mutect2, varscan2
- MAPRE1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 76/112 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65032604; called by muse, mutect2, varscan2
- MOCS1 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150364145, COSV57934329; called by muse, mutect2
- MROH6 | c.1707G>C p.L569F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV67338247; called by muse, mutect2, varscan2
- MUC17 | c.10616C>A p.T3539K | Missense Mutation (SNP) | VAF 70/412 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV60283136; called by muse, mutect2, varscan2
- NCOA3 | c.638C>G p.A213G | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1180308055, COSV100508214, COSV59073335; called by muse, mutect2
- NEFH | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV60215903, COSV60218889; called by muse, varscan2
- NINL | c.2117C>A p.P706H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.338); catalogued as rs1473654583, COSV53999934; called by muse, mutect2, varscan2
- NKX2-2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV65819289; called by muse, mutect2, varscan2
- NPRL2 | c.567G>C p.W189C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51600696, COSV51602957; called by muse, mutect2, varscan2
- NR3C2 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs201155740, COSV60987146; called by muse, mutect2, varscan2
- NUDC | c.529del p.T177Pfs*13 | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | catalogued as COSV58324817; called by mutect2, pindel, varscan2
- OBSCN | c.10432C>G p.P3478A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as COSV52753344, COSV52757886; called by muse, mutect2, varscan2
- OSGEP | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs920415662, COSV52831600; called by muse, mutect2
- PABPC4 | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63293306; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.898G>A p.A300T (on ENST00000259318 / NM_001136562.3; = p.A531T on NM_007203.5) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV99395726; called by muse, mutect2
- PARP1 | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV64689598; called by muse, mutect2, varscan2
- PARP1 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV64689604; called by muse, mutect2, varscan2
- PARP14 | c.4767G>C p.K1589N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV101506246, COSV71734272; called by muse, mutect2, varscan2
- PCDHA10 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 91/138 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV56485431; called by muse, mutect2, varscan2
- PHC2 | c.2294G>A p.G765D (on ENST00000257118 / NM_198040.2; = p.G230D on NM_004427.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV57102646; called by muse, mutect2, varscan2
- PPARG | c.286G>C p.D96H (on ENST00000287820 / NM_015869.5; = p.D66H on NM_005037.7) | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.891); catalogued as COSV55141514; called by muse, mutect2, varscan2
- PPCS | c.860A>T p.K287I | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV65333561; called by muse, mutect2, varscan2
- PSMD4 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as rs1362483909, COSV64393163; called by muse, mutect2, varscan2
- RAB40AL | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.207); catalogued as COSV99505285; called by muse, mutect2, varscan2
- RGL2 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV69915979; called by muse, mutect2, varscan2
- RGR | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs201335015, COSV100812996, COSV63893643; called by muse, mutect2, varscan2
- RNF111 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV62084389; called by muse, mutect2, varscan2
- RNF123 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 13/133 reads (10%) | catalogued as rs756933544, COSV100571204; called by muse, mutect2, varscan2
- RNF207 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs761708891, COSV65007334; called by muse, mutect2, varscan2
- RNF212 | c.90C>G p.C30W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61364095, COSV61364657; called by muse, varscan2
- RNPEP | c.478G>T p.G160* | Nonsense Mutation (SNP) | VAF 23/137 reads (17%) | catalogued as COSV99821861; called by muse, mutect2, varscan2
- RPGRIP1 | c.3048G>C p.K1016N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.518); catalogued as COSV52846819; called by muse, mutect2, varscan2
- S100A5 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs368286819, COSV63296735; called by muse, mutect2, varscan2
- SALL4 | c.2473C>G p.L825V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs757391872, COSV53850599; called by muse, mutect2, varscan2
- SCARF1 | c.2360C>T p.S787L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs774498375, COSV53957891; called by muse, mutect2, varscan2
- SDHA | c.339C>A p.N113K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53766475; called by muse, mutect2, varscan2
- SEL1L2 | c.279T>A p.N93K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs772081288, COSV53149373; called by muse, mutect2, varscan2
- SEPTIN1 | c.446+1G>C p.X149_splice (on ENST00000321367; = p.X102_splice on NM_052838.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as rs1424253875, COSV58441573; called by muse, mutect2, varscan2
- SLC13A3 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.421); catalogued as rs752242423, COSV51713110; called by muse, mutect2, varscan2
- SLC39A1 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as COSV57841529, COSV57842157; called by muse, mutect2, varscan2
- SLC6A19 | c.765C>A p.F255L | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58670220, COSV58675184; called by muse, mutect2, varscan2
- SLCO1C1 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs373359001, COSV56869679; called by muse, mutect2, varscan2
- SLITRK6 | c.1709T>C p.V570A | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1023233216, COSV68390719; called by muse, mutect2
- SPATA2L | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV57046234; called by muse, mutect2, varscan2
- SPESP1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.608); catalogued as COSV52986245; called by muse, mutect2, varscan2
- STAU1 | c.488A>T p.E163V (on ENST00000371856 / NM_001319135.1; = p.E82V on NM_004602.3) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV61459504; called by muse, mutect2
- TCEA3 | c.539G>A p.C180Y | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as COSV71531860; called by muse, mutect2
- TCTE3 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV64649667; called by muse, mutect2, varscan2
- TDRD10 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as COSV52724329; called by muse, mutect2, varscan2
- TELO2 | c.1840G>C p.D614H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1393443783, COSV51976579; called by muse, mutect2, varscan2
- TMEM192 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.121); catalogued as rs767705040, COSV60584750; called by muse, mutect2, varscan2
- TNPO1 | c.2563G>C p.D855H | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV61520690; called by muse, mutect2, varscan2
- TRRAP | c.4486G>C p.E1496Q | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.865); catalogued as COSV62841216; called by muse, mutect2, varscan2
- USP9X | c.1384C>G p.P462A | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV61067168; called by muse, mutect2, varscan2
- VPS13B | c.4821G>C p.Q1607H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as COSV62136530; called by muse, mutect2, varscan2
- VWA3B | c.2239C>G p.L747V | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.045); catalogued as COSV68241688; called by muse, mutect2, varscan2
- WDR18 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 38/91 reads (42%) | catalogued as COSV99243071; called by muse, mutect2, varscan2
- WDR33 | c.3761C>T p.S1254F | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV59247189; called by muse, mutect2, varscan2
- WWC2 | c.1672C>G p.P558A | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV66712911; called by muse, mutect2, varscan2
- XRRA1 | c.1322A>T p.H441L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.366); catalogued as COSV58496787; called by muse, mutect2, varscan2
- ZNF808 | c.1093C>A p.H365N | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63119111; called by muse, mutect2, varscan2
- HIVEP2 | c.7093G>A p.A2365T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); called by muse, mutect2
- PDS5B | c.2071del p.I691Ffs*65 | Frame Shift Del (DEL) | VAF 39/96 reads (41%) | called by mutect2, pindel, varscan2
- ABCA4 | c.2487G>A p.T829= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs770089512, COSV64671940; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ACSL6 | c.306C>A p.I102= (on ENST00000379240; = p.I127= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV57295847; called by muse, mutect2, varscan2
- AIFM3 | c.1680C>T p.S560= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99302298; called by muse, mutect2
- CCHCR1 | c.1686G>A p.L562= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs1405567011, COSV52545621; called by muse, mutect2, varscan2
- CENPB | c.798G>A p.K266= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100713621; called by muse, mutect2
- CHD8 | c.2019G>A p.K673= (on ENST00000646647 / NM_001170629.2; = p.K394= on NM_020920.4) | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV101303212, COSV67870205; called by muse, mutect2, varscan2
- CHST11 | c.372C>G p.P124= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV57985230; called by muse, mutect2, varscan2
- COL6A2 | c.69G>A p.Q23= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV56001503; called by muse, mutect2, varscan2
- CTDSPL | c.516C>G p.A172= (on ENST00000273179 / NM_001008392.2; = p.A161= on NM_005808.3) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99829034; called by muse, mutect2
- DOCK10 | c.5778G>A p.V1926= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99291597; called by muse, mutect2, varscan2
- EPHA8 | c.1758T>C p.N586= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs770764501, COSV51264590; called by muse, mutect2, varscan2
- FILIP1L | c.201C>T p.L67= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV58766286, COSV58766765; called by muse, mutect2, varscan2
- FOCAD | c.2475G>A p.K825= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs1189460970, COSV58095566; called by muse, mutect2, varscan2
- GGNBP2 | c.1824A>G p.A608= | Silent (SNP) | VAF 30/181 reads (17%) | called by muse, mutect2, varscan2
- GSS | c.993C>T p.L331= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV53623551, COSV53628484; called by muse, mutect2, varscan2
- ITSN1 | c.3219A>G p.G1073= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs1327533622, COSV66081680; called by muse, mutect2, varscan2
- MARF1 | c.5154C>T p.S1718= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs763192693, COSV60020927; called by muse, mutect2, varscan2
- NLRP11 | c.1674G>T p.V558= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs771136815, COSV64086226; called by muse, mutect2, varscan2
- NRG2 | c.1326G>A p.R442= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV56830746; called by muse, mutect2, varscan2
- NRM | c.609G>C p.L203= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV51294938; called by muse, mutect2, varscan2
- OPA3 | c.459C>T p.R153= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs748075455, COSV55606198; called by muse, mutect2, varscan2
- OR5I1 | c.255C>G p.V85= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV56885929; called by muse, mutect2, varscan2
- OSBPL10 | c.1305C>T p.F435= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV67337408; called by muse, mutect2, varscan2
- PDK2 | c.336C>T p.F112= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99143096; called by muse, mutect2, varscan2
- PTPRM | c.3231G>T p.V1077= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs761957219, COSV59849410; called by muse, mutect2, varscan2
- RAP1B | c.222T>C p.N74= | Silent (SNP) | VAF 82/159 reads (52%) | catalogued as COSV51667733; called by muse, mutect2, varscan2
- RBMS3 | c.1011A>G p.T337= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1347231276, COSV99824185; called by muse, mutect2
- RELB | c.1506G>T p.L502= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1201718670, COSV55509104; called by muse, mutect2, varscan2
- S1PR1 | c.189C>T p.N63= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1443622120, COSV59512794; called by muse, mutect2, varscan2
- SLIT3 | c.2382C>G p.T794= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV60592630, COSV60597457; called by muse, mutect2, varscan2
- TBX18 | c.693G>A p.S231= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs200601121, COSV63736365; called by muse, mutect2, varscan2
- TRIM11 | c.1008C>T p.R336= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99488978; called by muse, mutect2
- ZC3H13 | c.3147G>A p.K1049= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as COSV54449955; called by muse, mutect2, varscan2
- ZNF253 | c.118T>C p.L40= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs1160740906, COSV63036663; called by muse, mutect2, varscan2
- ZNF48 | c.870C>T p.L290= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV60782572; called by muse, mutect2, varscan2
- AADAC | c.-2C>T | 5'UTR (SNP) | VAF 20/131 reads (15%) | catalogued as rs1363224805, COSV99233363; called by muse, mutect2, varscan2
- ANKRD13D | c.*511T>A | 3'UTR (SNP) | VAF 7/60 reads (12%) | catalogued as COSV57751242; called by muse, mutect2, varscan2
- NACA | c.71-4019C>A | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as rs764359969, COSV63268536; called by muse, mutect2, varscan2
- NLRP7 | c.2810+2736C>T | Intron (SNP) | VAF 13/92 reads (14%) | catalogued as COSV60172184; called by muse, mutect2
- RPS27 | c.-1C>T | 5'UTR (SNP) | VAF 26/59 reads (44%) | catalogued as rs754848441, COSV99669093; called by muse, mutect2, varscan2
